Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-ABO1, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-ABO1-TTP1-A (Primary Tumor).

[page 1 of 50]
Entry Date

+522

Component Results

Component Value

Pathology Report

(NOTE)

SURGICAL PATHOLOGY REPORT

* Amended *

Case No:

Date Collected:

+0

Date Received:

+0

Referred by:

Copy To:

Tissue:

- 1: RIGHT TUBE + OVARY
- 2: RIGHT EXT ILIAC NODES
- 3: SIGMOID NODULE
- 4: UTERUS CERVIX LEFT TUBE + OVARY SO
- 5: SPLEEN + OMENTUM

Clinical Diagnosis:

Pelvic mass, splenic lesion.

ICD-9 code is not provided.

Gross Description:

The specimen is received in five parts.

Part one is received fresh, labeled with the patient's name [REDACTED] and medical record number [REDACTED], and designated "right tube and ovary". The specimen consists of a 300 gm salpingo oophorectomy. The specimen measures 12.0 x 7.0 x 7.5 cm overall and is bi-lobed in appearance. There is a 7.0 x 2.5 x 0.7 cm portion of peripherally-associated fat received with the specimen. Sectioning reveals a solid component of the ovary measuring 7.0 x 6.0 x 6.5 cm overall. There is no visible surface excrescence. Grossly, there is an area of hair that is consistent with a dermoid cyst. There is an attached segment of fallopian tube measuring 7.3 cm in length with an average diameter of 1.0 cm. A representative portion of the solid component of the ovarian mass is submitted for frozen section diagnosis. The diagnosis reads, "FSA: Ovary, right, oophorectomy: Poorly differentiated serous adenocarcinoma (in cystic teratoma on gross exam). [REDACTED] and called to the OR at [REDACTED]. The frozen section control is submitted in cassette 1A. Additional representative sections are submitted as follows:

- 1B: Representatives of fallopian tube
- 1C: Representative of dermoid cyst
- 1D: Additional representatives of solid portion of ovary

Part two is received fresh, labeled with the patient's name [REDACTED] and

[page 2 of 50]
medical record number [REDACTED] and designated "right external iliac node". The specimen consists of two pieces of red-yellow soft tissue, one measuring 2.3 x 1.7 x 0.5 cm and the other measuring 2.0 x 1.2 x 0.6 cm. A lymph node search is conducted revealing two lymph node candidates measuring 1.4 and 1.6 cm in greatest dimensions, respectively. Cassettes are submitted as follows:

- 2A: One lymph node candidate, bisected
- 2B: One lymph node candidate, bisected
- 2C: Remaining fibrous tissue

Part three is received fresh, labeled with the patient's name [REDACTED] and medical record number [REDACTED], and designated "sigmoid nodule". The specimen consists of two portions of fibroadipose tissue. The first measures 6.0 x 2.5 x 1.5 cm and contains a 1.5 x 1.5 x 1.5 cm tan nodule. The second fragment of fibroadipose tissue measures 4.0 x 3.5 x 1.2 cm and contains a 1.5 x 1.4 x 1.2 cm tan solid nodule. Representative sections are submitted as follows:

- 3A: Two representative sections of nodule from tissue fragment #1
- 3B: Two representative sections of nodule from tissue fragment #2

Part four is received fresh, labeled with the patient's name [REDACTED] and medical record number [REDACTED], and designated "uterus-cervix, left tube and ovary". The specimen consists of a total hysterectomy with unilateral salpingo-oophorectomy weighing 140 gm. The uterus measures 11.3 x 5.7 x 5.3 cm. The cervix measures 3.5 x 3.4 x 2.2 cm with a 0.7 cm slit-like os. The anterior serosal surface is remarkable for an area of prominent nodularity measuring 5.5 x 3.3 x 3.0 cm that is suspicious for metastatic involvement. The left tube and ovary weighs 17.8 gm. The tube measures 4.5 cm in length x 0.5 cm in diameter. The ovary measures 3.0 x 2.7 x 1.2 cm and is remarkable for the presence of two nodules 0.9 and 2.7 cm in greatest dimension, respectively that are suspicious for metastatic involvement. The posterior surface of the uterus is marked with orange ink and the anterior surface is marked with blue ink. The specimen is bivalved to reveal the presence of a hemorrhagic mass in the uterine fundus measuring 2.0 cm in greatest dimension that is suspicious for metastatic involvement. Representative sections are submitted as follows:

- 4A: Representatives of fallopian tube
- 4B-C: Representative sections of ovary with nodules
- 4D: Anterior cervix
- 4E: Posterior cervix
- 4F: Uterine fundus with endometrial lesion
- 4G: Representatives of candidate leiomyoma
- 4H: Representatives of anterior serosal mass
- 4I: Anterior endomyometrium
- 4J: Posterior endomyometrium

Part five is received fresh, labeled with the patient's name [REDACTED] and medical record number [REDACTED], and designated "spleen and omentum". The specimen consists of a 380 gm splenectomy measuring 15.0 x 10.1 x 5.7 cm with an attached fragment of fibroadipose tissue measuring 13.0 x 6.5 x 3.4 cm containing a 5.8 x 3.5 x 3.4 cm solid tan papillary nodule suspicious for metastatic involvement. The fragment of this nodule is submitted for tissue procurement personnel. The container also contains a 480 gm omentectomy measuring 49.0 x 18.0 x 4.5 cm overall. The specimen is remarkable for a 15.0 x 7.5 x 4.5 cm region of hemorrhagic nodularity at one end that is suspicious for metastatic disease. Representative sections are submitted as follows:

- 5A: Representatives of spleen in relation to tan perisplenic nodule

[page 3 of 50]
5B: Representatives of grossly normal spleen
5C-E: Representatives of omental nodularity

CASSETTE SUMMARY

Part 1, rep, 4 blocks
Part 2, all, 3 blocks
Part 3, rep, 2 blocks
Part 4, rep, 10 blocks
Part 5, rep, 5 blocks
Total slides: 24 H+E
Total blocks: 24

+3

Intraoperative Consult:

FS1A: Ovary, right, oophorectomy: Poorly differentiated serous adenocarcinoma (in cystic teratoma on gross exam).

Note:

SYNOPTIC REPORTING FORM FOR OVARY, OOPHORECTOMY, SALPINGO-OOPHORECTOMY, SUBTOTAL OOPHORECTOMY OR REMOVAL OF TUMOR IN FRAGMENTS, HYSTERECTOMY WITH SALPINGO-OOPHORECTOMY:

MACROSCOPIC

SPECIMEN TYPE: Hysterectomy with salpingo-oophorectomy.

PRIMARY TUMOR SITE: Diffuse bilateral ovarian involvement, primary site cannot be determined.

SPECIMEN INTEGRITY: Right ovary intact. Left ovary intact.

TUMOR SIZE: Right ovary: Greatest dimension: 7.0 cm.
Left ovary: Greatest dimension: 2.7 cm.

MICROSCOPIC

HISTOLOGIC TYPE: Serous carcinoma, clear cell carcinoma.

HISTOLOGIC GRADE: Poorly differentiated.

PATHOLOGIC STAGING:

Primary Tumor (pT): pT3 and/or N1: Peritoneal metastasis beyond pelvis more than 2.0 cm in greatest dimension and/or regional lymph node metastasis.

Regional Lymph Nodes (pN): pN1: Regional lymph node metastasis.

Specify: Number examined: 2 ; Number involved: 2

Distant Metastasis (pM): pMX: Cannot be assessed.

SUMMARY OF ORGANS/TISSUES MICROSCOPICALLY INVOLVED BY TUMOR: Both ovaries, omentum, uterus, sigmoid colon, serosa.

NOTE:

We favor the endometrial involvement in part 4 as representing ingrowth from the ovarian lesion, rather than a separate endometrial primary.

[page 4 of 50]
Concurrent cytologic analysis of peritoneal/ascites fluid (see [REDACTED])
preliminarily reveals atypical cells consistent with involvement by carcinoma.

Diagnosis:

OVARY AND FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY:

OVARY:

POORLY DIFFERENTIATED CARCINOMA WITH CLEAR CELL AND SEROUS FEATURES.

(See synoptic report.)

MATURE CYSTIC TERATOMA.

FALLOPIAN TUBE:

NO PATHOLOGIC ABNORMALITY.

LYMPH NODES (2), EXTERNAL ILIAC, RIGHT, BIOPSY:

METASTATIC ADENOCARCINOMA (2/2).

SOFT TISSUE, SIGMOID NODULE, BIOPSY:

POORLY DIFFERENTIATED CARCINOMA.

UTERUS, TOTAL HYSTERECTOMY WITH LEFT

SALPINGO-OOPHORECTOMY:

FALLOPIAN TUBE, LEFT:

NO PATHOLOGIC ABNORMALITY.

OVARY, LEFT:

POORLY DIFFERENTIATED SEROUS CARCINOMA

CERVIX:

SEROUS PAPILLARY CARCINOMA.

ENDOMETRIUM:

SEROUS PAPILLARY CARCINOMA. (See note).

MYOMETRIUM:

LEIOMYOMA.

UTERINE SEROSA:

SEROUS PAPILLARY CARCINOMA.

SPLEEN AND OMENTUM, SPLENECTOMY AND OMENTECTOMY:

SPLEEN:

CAPSULAR INVOLVEMENT BY SEROUS PAPILLARY CARCINOMA.

OMENTUM:

SEROUS PAPILLARY CARCINOMA.

88307, 88309, 88305 x 2, 88331

***Electronically Signed Out By [REDACTED] +13

By my electronic signature affixed below, I affirm that I have reviewed this report and all pathologic materials + information pertaining to this case with the resident/fellow physicians listed, and that I am personally responsible for all stated diagnoses in this report.

Procedures/Addenda:

Addendum Date Ordered: [REDACTED] Status: Signed Out +7

Date Complete: [REDACTED]

By: [REDACTED]

Date Reported: [REDACTED]

[page 5 of 50]
Addendum Diagnosis
{Not Entered}

Addendum Comment

The primary tumor site within the synoptic should be listed as "diffuse bilateral ovarian involvement, primary side cannot be determined." The right ovary had a larger tumor burden than the left, and we favor that the lesion likely arose from the right ovary.

[REDACTED] M.D.
[REDACTED] M.D.

Amendments:

Amended: [REDACTED] by [REDACTED] +6

Reason: Typographical Error

Typing error ("side" not site) in synoptic report tumor site, also added an additional comment per [REDACTED]

Previous Signout Date: [REDACTED] +4

Lab and Collection

SURGICAL PATHOLOGY BIOPSY/OTHER on [REDACTED] +0

SURGICAL PATHOLOGY BIOPSY/OTHER

+522

Ordering Physician

User Interface

Result Information

Status

Edited [REDACTED] PM) +522

Provider Status

Ordered

View SmartLink Info

SURGICAL PATHOLOGY BIOPSY/OTHER (Order [REDACTED] on [REDACTED] +0

Results Routing Details for Order:

Results contact on [REDACTED] Edited [REDACTED]

Outcome: +522 Result not sent

Resulting User: [REDACTED]

Routing Instant: [REDACTED]

Comments: Message not sent because the HISTORIC profile variable is set to 1

Current Status: Routing Complete

Status History: Result contact created [REDACTED] +522

Routing Complete Tue [REDACTED] +522

Results Tracking

Order Description

SURGICAL
PATHOLOGY
BIOPSY/OTHER

Order ID

Instant of Order

+0

Order Class

Normal

Ordering User

Authorizing Provider
User Interface

Procedure
SURGICAL
PATHOLOGY
BIOPSY/OTHER

Proc. Category
PATHOLOGY/CYTOLOGY
ORDERABLES [8]

Abnormal?

Encounter Provider

Encounter Department

Encounter Date

Encounter
Type

CSN

[page 6 of 50]
Results Routing Outcome
Result not sent

Scheme Used

Line

Resulting User

Hospital
Encounter

Result
Time

Result Date
+522

Message not sent because the HISTORIC profile variable is set to 1

Routing Information

This letter was not routed.

SURGICAL PATHOLOGY BIOPSY/OTHER

(Order

Lab

Order:

Released By: Auto-
released
Authorizing: User
Interface

Date: +522
Department:
Gynecology

Order Information

Order Date/Time

Release Date/Time

Start Date/Time

End Date/Time

+0

+0

+0

+0

Order Details

Frequency
ONCE

Duration
1 occurrence

Priority
Routine

Order Class
Normal

Order Providers

Authorizing Provider
User Interface

Encounter Provider:

Reprint Outpatient Order Requisition

SURGICAL PATHOLOGY BIOPSY/OTHER (Order
on +0

Reprint Inpatient Order Requisition

SURGICAL PATHOLOGY BIOPSY/OTHER (Order
on +0

Original Order

Ordered On

Ordered By

Order #

+0

Comments

Ordered by an unspecified provider

Lab Collection Information

Collected: +0

Patient Information

Additional Information

Associated Reports
View Encounter
Priority and Order Details
Collection Information.

External References
Lab Manual

No order transmittal information available.

Order may not have completed order transmittal.

[page 7 of 50]
Description

Telephone Encounter Date of Service: +2608

returned my call and we reviewed the results of the second and final step of her genetic testing.

tested **POSITIVE** for a mutation in PMS2 called c.809C>G (p.Ser270*). She tested **negative** for mutations in APC, ATM, BARD1, BMPR1A, BRCA1, BRCA2, BRIP1, CDH1, CDK4, CDKN2A, CHEK2, EPCAM, MLH1, MSH2, MSH6, MUTYH, NBN, PALB2, PTEN, RAD51C, RAD51D, SMAD4, STK11, and TP53.

SPECIMEN

Specimen Type: Blood
Draw Date:
Accession Date:
Report Date:

+2588
+2590
+2607

Gender: Female
Accession #:
Requisition #:

ORDERING PHYSICIAN:

**RESULT: POSITIVE - CLINICALLY SIGNIFICANT MUTATION IDENTIFIED**

Note: "CLINICALLY SIGNIFICANT" as defined in this report, is a genetic change that is associated with the potential to alter medical intervention.

GENE	MUTATION	INTERPRETATION
PMS2	c.809C>G (p.Ser270*) Heterozygous	High Cancer Risk This patient has Lynch syndrome/Hereditary Non-Polyposis Colorectal Cancer (HNPCC).

DETAILS ABOUT: PMS2 c.809C>G (p.Ser270*): NM_005356.5; (aka: S270X (809C>G))

Functional Significance: Deleterious - Abnormal Protein Production and/or Function

The heterozygous germline PMS2 mutation c.809C>G is predicted to result in the premature truncation of the PMS2 protein at amino acid position 270 (p.Ser270*).

Clinical Significance: High Cancer Risk

This mutation is associated with increased cancer risk and should be regarded as clinically significant.

ADDITIONAL FINDINGS: NO VARIANT(S) OF UNCERTAIN SIGNIFICANCE (VUS) IDENTIFIED

Details About Non-Clinically Significant Variants: All individuals carry DNA changes (i.e., variants), and most variants do not increase an individual's risk of cancer or other diseases. When identified, variants of uncertain significance (VUS) are reported. Likely benign variants (Favor Polymorphisms) and benign variants (Polymorphisms) are not reported and available data indicate that these variants most likely do not cause increased cancer risk. Present evidence does not suggest that non-clinically significant variant findings be used to modify patient medical management beyond what is indicated by the personal and family history and any other clinically significant findings.

Variant Classification: Myriad's myVariant™ Variant Classification Program performs ongoing evaluations of variant classifications. In certain cases, healthcare providers may be contacted for more clinical information or to arrange family testing to aid in variant classification. When new evidence about a variant is identified and determined to result in clinical significance and management change, that information will automatically be made available to the healthcare provider through an amended report.

[page 8 of 50]
Accession # [REDACTED]

Report Date [REDACTED]

+2608

ADDITIONAL INFORMATION**GENES ANALYZED**

Unless otherwise noted sequencing and large rearrangement analyses were performed on the following genes:

APC, ATM, BARD1, BMPR1A, BRCA1, BRCA2, BRIP1, CDH1, CDK4, CDKN2A, CHEK2, EPCAM (large rearrangement only), MLH1, MSH2, MSH6, MUTYH, NBN, PALB2, PMS2, PTEN, RAD51C, RAD51D, SMAD4, STK11, TP53.

** Other genes not analyzed with this test may also be associated with cancer.

Indication for Testing: It is our understanding that this individual was identified for testing due to a personal or family history suggestive of a hereditary predisposition for cancer.

Associated Cancer Risks and Clinical Management: Please see the "myRisk Management Tool" associated with this report for a summary of cancer risk and professional society medical management guidelines that may be useful in developing a plan for this patient based on test results and reported personal/family history. If applicable, Testing of other family members may assist in the interpretation of this patient's test result.

Analysis Description: The Technical Specifications summary (<https://www.myladpro.com/myrisk/documents-and-forms/>) describes the analysis, method, performance, nomenclature, and interpretive criteria of this test. The classification and interpretation of all variants identified in this assay reflects the current state of scientific understanding at the time this report was issued, and may change as new scientific information becomes available. Current testing technologies are unable to definitively determine whether a variant is germline or somatic in origin, which may significantly impact risk estimates and medical management; therefore, these results should be correlated with this patient's personal and family history. The interpretation of this test may also be impacted if the patient has a hematologic malignancy or an allogeneic bone marrow transplant.

[REDACTED] and I reviewed that this means she does have Lynch syndrome.

Individuals who have Lynch syndrome have an increased risk to develop cancer in their lifetime in comparison to the general population. Some of the cancers that individuals with PMS2-associated Lynch syndrome are at increased risk for include: colon and endometrial cancers. Other cancer types have been observed in some men and women with PMS2 mutations, including ovarian, gastric, and other cancers.

While not everyone who has a mutation in PMS2 will develop cancer, according to the NCCN the currently estimated lifetime risks for individuals carrying a mutation in PMS2 to age 70 are:

[page 9 of 50]
National
Comprehensive
Cancer
Network

NCCN Guidelines Version 2.2015 Lynch Syndrome

NCCN Guidelines for
Lynch Syndrome
Discussion

Cancer Risk Up to Age 70 Years in Individuals with Lynch Syndrome Compared to the General Population

Cancer	General Population Risk ¹	MLH1 or MSH2 ^{1,2}		MSH6 ²		PMS2 ³	
		Risk	Mean Age of Onset	Risk	Mean Age of Onset	Risk	Mean Age of Onset
Colon	6.5%	40%–80%	44–61 years	10%–22%	54 years	15%–20%	61–66 years
Endometrium	2.7%	25%–60%	48–62 years	16%–26%	55 years	15%	49 years
Stomach	<1%	1%–13%	56 years	53%	63 years	+	70–78 years
Ovary	1.6%	4%–24% ⁴	42.5 years	1%–11%	46 years	+	42 years
Hepatobiliary tract	<1%	1.4%–4%	50–57 years	Not reported	Not reported	+	Not reported
Urinary tract	<1%	1%–4%	64–69 years	<1%	65 years	+	Not reported
Small bowel	<1%	3%–6%	47–49 years	Not reported	54 years	+	59 years
Brain/CNS	<1%	1%–3%	~50 years	Not reported	Not reported	+	45 years
Sebaceous neoplasms	<1%	1%–9%	Not reported	Not reported	Not reported	Not reported	Not reported
Pancreas ⁴	<1%	1%–6%	Not reported	Not reported	Not reported	Not reported	Not reported

¹Adapted from Kollmann W, Gruber SB (Updated September 20, 2012) Lynch Syndrome. In: GeneReviews at GeneTests. Medical Genetics Information Resource (database online). Copyright, University of Washington, Seattle 1993-2014. Available at <http://www.genetests.org>. Accessed February 21, 2014.

²Bonadona V, Bonatti B, Olschwig S, et al. French Cancer Genetics Network. Cancer risks associated with germline mutations in MLH1, MSH2, and MSH6 genes in Lynch syndrome. JAMA 2011;305:2384-2390.

³Senior L, Clendenning M, Solomon K, et al. The clinical phenotype of Lynch syndrome due to germline PMS2 mutations. Gastroenterology 2008;135:410-428.

⁴Kashinos F, Mukherjee B, Tayob N, et al. Risk of pancreatic cancer in families with Lynch syndrome. JAMA 2009;302:1780-1795.

⁵The 24% risk reported in Bonadona V et al (JAMA 2011;305:2384-2390) included wide confidence intervals (1%–66% for MLH1, 3%–52% for MSH2).

[†]The combined risk for renal pelvis, stomach, ovary, small bowel, ureter, and brain is 6% to age 70 (Senior L, et al. Gastroenterology 2008;135:410-428).

Notes: All recommendations are category 2A unless otherwise indicated.

Clinical Trials: NCCN believes that the best management of any cancer patient is in a clinical trial. Participation in clinical trials is especially encouraged.

Version 2.2015 10/27/15 © National Comprehensive Cancer Network, Inc. 2015. All rights reserved. The NCCN Guidelines® and this illustration may not be reproduced in any form without the express written permission of NCCN.

LS-D

Due to these elevated risks, additional screening is recommended. These screening plans typically begin when a person is between the ages of 25 and 30, or 3 to 5 years younger than the youngest age of diagnosis in the family, whichever is younger. Therefore, individuals in Ms. [redacted] family found to carry this mutation should consider screening beginning around age [redacted] to [redacted] given [redacted] diagnosis at age [redacted].

The NCCN Guidelines for screening and management for individuals who carry a PMS2 mutation are:

[page 10 of 50]
National
Comprehensive
Cancer
Network[®]

NCCN Guidelines Version 2.2015 Lynch Syndrome

NCCN Guidelines Index
Lynch Syndrome, T1
Discussion

LYNCH SYNDROME MANAGEMENT

Surveillance for *MLH1*, *MSH2*, and *EPCAM* Mutation Carriers¹

Colon cancer:

- Colonoscopy at age 20–25 y or 2–5 y prior to the earliest colon cancer if it is diagnosed before age 25 y and repeat every 1–2 y.
- There are data to suggest that aspirin may decrease the risk of colon cancer in LS; however, at this time the data are not sufficiently robust to make a recommendation for its standard use.

Extracolonic:

- Endometrial and ovarian cancer:
- ▶ Prophylactic hysterectomy and bilateral salpingo-oophorectomy (BSO) is a risk-reducing option that should be considered by women who have completed childbearing.
- ▶ Patients must be aware that dysfunctional uterine bleeding warrants evaluation.
- ▶ There is no clear evidence to support screening for endometrial cancer for LS. However, annual office endometrial sampling is an option.
- ▶ While there may be circumstances where clinicians find screening helpful, data do not support routine ovarian screening for LS. Transvaginal ultrasound for ovarian and endometrial cancer has not been shown to be sufficiently sensitive or specific as to support a positive recommendation, but may be considered at the clinician's discretion. Serum CA-125 is an additional ovarian screening test with caveats similar to transvaginal ultrasound.
- Gastric and small bowel cancer: There is no clear evidence to support screening for gastric, duodenal, and small bowel cancer for LS. Selected individuals or families or those of Asian descent⁴ may consider EGD with extended duodenoscopy (to distal duodenum or into the jejunum) every 3–5 y beginning at age 30–35 y.
- Urothelial cancer: Consider annual urinalysis starting at 25–30 y.
- Central nervous system (CNS) cancer: Annual physical/neurologic examination starting at 25–30 y; no additional screening recommendations have been made.
- Pancreatic cancer: Despite data indicating an increased risk for pancreatic cancer, no effective screening techniques have been identified; therefore, no screening recommendation is possible at this time.
- Breast cancer: There have been suggestions that there is an increased risk for breast cancer in LS patients; however, there is not enough evidence to support increased screening above average-risk breast cancer screening recommendations.

See Follow-up
of Surveillance
Findings (LS-5)

¹See Cancer Risk Up to Age 70 Years in Individuals with Lynch Syndrome Compared to the General Population (LS-3)

⁴Other than colon and endometrial cancer, screening recommendations are expert opinion rather than evidence-based.

See Surveillance for *MSH6* and *PMS2* Mutation Carriers (LS-4)

⁴Vasen HF, Blanco I, Aktan-Collik K, et al. Revised guidelines for the clinical management of Lynch syndrome (HNPCC): Recommendations by a group of European experts. Gut 2013;62:812–823

Note: All recommendations are category 2A unless otherwise indicated.

Clinical Trials: NCCN believes that the best management of any cancer patient is in a clinical trial. Participation in clinical trials is especially encouraged.

Version 2.2015 | © 2015 National Comprehensive Cancer Network, Inc. All rights reserved. The NCCN Guidelines and this illustration may not be reproduced in any form without the express written permission of NCCN.

LS-3

National
Comprehensive
Cancer
Network[®]

NCCN Guidelines Version 2.2015 Lynch Syndrome

NCCN Guidelines Index
Lynch Syndrome, T1
Discussion

LYNCH SYNDROME MANAGEMENT

Surveillance for *MSH6* and *PMS2* Mutation Carriers¹

Colon cancer:

- Colonoscopy¹ at age 25–30 y or 2–5 y prior to the earliest colon cancer if it is diagnosed before age 30 y and repeat every 1–2 y

Extracolonic:

- For endometrial and ovarian cancer, see surveillance for *MLH1*, *MSH2*, and *EPCAM* mutation carriers (See LS-3).
- The risk of other LS-related cancers is reportedly low;¹ however, due to limited data no screening recommendation is possible at this time.

See Follow-up
of Surveillance
Findings (LS-5)

Risk to Relatives

- Advise relatives about possible inherited cancer risk, options for risk assessment, and management.
- Recommend genetic counseling and consideration of genetic testing for at-risk relatives.

Reproductive Options

- For patients of reproductive age, advise about options for prenatal diagnosis and assisted reproduction including pre-implantation genetic diagnosis. Discussion should include known risks, limitations, and benefits of these technologies.
- For patients of reproductive age, advise about the risk of a rare recessive syndrome (constitutional mismatch repair deficiency [CMMRD syndrome]^{2m}) if both partners are a carrier of a mutation/s in the same MMR gene or *EPCAM* (example, both partners carry a mutation in the *PMS2* gene, then their future offspring have a risk for CMMRD syndrome).

¹See Cancer Risk Up to Age 70 Years in Individuals with Lynch Syndrome Compared to the General Population (LS-3)

^{2m}There are limited data to suggest definitive recommendations for when to initiate screening. Current data suggest that *MSH6* and *PMS2* mutation carriers have significantly lower risks for colorectal and certain extracolonic cancers compared to *MLH1*, *MSH2*, and *EPCAM* mutation carriers. However, given the limited data and variability in the ages of onset and penetrance among *MSH6* and *PMS2* carriers, colonoscopies starting at younger or later ages may be considered in some families.

^{2m}Wimmer K, Kralz CP, Vasen HF, et al. EU Consortium Care for CMMRD (C4CMMRD): Diagnostic criteria for constitutional mismatch repair deficiency syndrome: suggestions of the European consortium 'care for CMMRD' (C4CMMRD). J Med Genet 2014;51:355–365

Note: All recommendations are category 2A unless otherwise indicated.

Clinical Trials: NCCN believes that the best management of any cancer patient is in a clinical trial. Participation in clinical trials is especially encouraged.

Version 2.2015 | © 2015 National Comprehensive Cancer Network, Inc. All rights reserved. The NCCN Guidelines and this illustration may not be reproduced in any form without the express written permission of NCCN.

LS-4

[page 11 of 50]
At this time, we cannot be sure which side of Ms. [REDACTED] family this mutation is being passed down from. Therefore, it is appropriate for other family members to consider testing in order to determine their potential cancer risks as well as to better inform us of who in the family may be at risk. [REDACTED] mother may be an appropriate candidate to consider testing in order to help provide information about who else in the family may be at risk. I will be glad to coordinate appointments with [REDACTED] family members or can offer them the contact information for genetic counselors in their area should they wish to meet with someone closer to their homes.

Mutations in PMS2 are inherited in an autosomal dominant manner. Given [REDACTED] positive test result, her half siblings have up to a 50% chance of also testing positive for this mutation in PMS2. There are not thought to be any pediatric cancer risk associated with monoallelic mutations in PMS2, therefore we do not generally offer testing to individuals under age 18.

Inheriting mutations in each copy of PMS2 (one from a child's mother and one from a child's father, referred to as biallelic) is associated with a condition called Constitutional Mismatch Repair Deficiency (CMMRD). Individuals who test positive for a mutation in PMS2 and are considering having children may choose to consult with a prenatal genetic counselor if they wish to discuss the potential risks for their future children to have CMMRD.

I encouraged [REDACTED] to share this information and the results of her genetic testing with her family as she feels comfortable.

[REDACTED] that this result explained her diagnosis. She was interested in establishing care with a GI group and requested a referral which I have placed. She is looking forward to meeting with physicians from this group to discuss and plan an effective screening plan for herself.

I spent approximately 10 minutes reviewing this information with [REDACTED]

[REDACTED]
Certified Genetic Counselor
[REDACTED]

Telephone on [REDACTED]

+2608

[page 12 of 50]
CT CHEST W CONTRAST

Status: Final result

Procedure ID: [REDACTED]

Images on Full PACS (Caresstream)

Show images for CT CHEST W CONTRAST

Images on PACS Light (VueMotion)

Show images for CT CHEST W CONTRAST

Images on PACS Light (External [REDACTED] Provider)

Show images for CT CHEST W CONTRAST

Study Result

IMPRESSION:

1. Interval enlargement of well-defined, solely right middle lobe pulmonary nodule which now measures up to 16 mm in diameter, consistent with progression of metastatic lesion to the lungs. This lesion is amenable for percutaneous image guided biopsy if clinically indicated.
2. An additional 2 mm peribronchovascular nodule in the same lobe is stable from prior, possibly representing a small subsegmental lymph nodes. No new metastatic lesions to the lungs.
3. No findings to suggest nodal metastatic involvement in the mediastinum.
4. Please see dedicated abdominal pelvic CT examination of the same date for detail on findings below the diaphragm.

[REDACTED]
Attending Radiologist
Thoracoabdominal imaging division

Chest CT with contrast

History: History of ovarian neoplasia. Followup.

Comparison: Chest CT dated [REDACTED] +1279 Chest CT dated [REDACTED] +1111

Technique: Volumetric acquisition of the chest was obtained from the thoracic inlet to the adrenal glands after administration of 100 mL of IV contrast, without immediate complication. Sagittal and coronal reformats were performed.

FINDINGS:

The supraaortic branches, thoracic aorta and main pulmonary artery are normal in caliber. There is mild enlargement of the ventricle, stable from prior. No pericardial effusion.

[page 13 of 50]
The thyroid gland is normal. The central airways are patent. Normal sized mediastinal and bilateral hilar lymph nodes. No evidence of axillary or supraclavicular adenopathy. The esophagus is normal.

Redemonstration of progressive enlargement of the right middle lobe, solid well-defined nodule which demonstrates a homogeneous low attenuation and now measures up to 16 mm in diameter, consistent with an additional 2 mm nodule in the same lobe is stable from prior, possibly representing a small peribronchial lymph node. No new pulmonary nodules are identified.

The pleural spaces are normal.

Please see dedicated abdominal pelvic CT examination of the same date for detail on findings below the diaphragm.

No aggressive osseous lesions are noted.

Imaging

CT CHEST W CONTRAST (Order # [REDACTED]) on [REDACTED] - Imaging Information
+1489

Result History

CT CHEST W CONTRAST (Order # [REDACTED]) on [REDACTED] - Order Result History Report
+1489

Imaging Information

Exam Information

Performed Procedure	Study Status	Begin Time	End Time
CT CHEST W CONTRAST	Final	[REDACTED] +1489	[REDACTED] +1489

Staff Information

Technologist	Transcriptionist	Assigned Physician(s)	Assigned Pool(s)
[REDACTED]	N/A	N/A	N/A

Verification Information

Signed By	Signed On	Marked as Prelim By	Marked as Prelim On
[REDACTED] MD	[REDACTED] +1489	[REDACTED]	

Read By

Read	Date
[REDACTED]	[REDACTED] +1489

Signed By

Signed	Date/Time	Phone	Pager
[REDACTED]	[REDACTED] +1489	[REDACTED]	[REDACTED]

Radiology Faculty Web Page

Radiology Faculty Web Page

[page 14 of 50]
External Result Report

External Result Report

AM +1503

PM +1494

Reason For Exam

ovarian cancer evaluate for efficacy of chemo, compare to prior

Dx: Ovarian cancer [183.0 (ICD-9-CM)]

Diagnosis

Malignant neoplasm of ovary

Codes

ICD-10-CM C56.9

ICD-9-CM 183.0

Comments

Associated Diagnoses

Ovarian cancer

Other Encounter Related Information

Encounter Charges

IE

CT CHEST W CONTRAST (Order

Imaging

Date: Department: Radiology CT Released By:

Authorizing:

+1489

Procedure ID:

Link to CPT Codes

CPT Codes

Order Information

Order Date/Time

AM

+1489

Release Date/Time

AM

+1489

Start Date/Time

+1489

End Date/Time

None

Order Details

Frequency

None

Duration

1 occurrence

Priority

Routine

Order Class

Ancillary Performed

Order Providers

Authorizing
ProviderEncounter
Provider

Billing Provider

Reprint Imaging Requisition

CT CHEST W CONTRAST (Order

on

+1489

Original Order

Ordered On

+1370

Ordered By

[page 15 of 50]
Reason For Exam

ovarian cancer evaluate for efficacy of chemo, compare to prior
Dx: Ovarian cancer [183.0 (ICD-9-CM)]

Associated Diagnoses

	ICD-10-CM	ICD-9-CM
Ovarian cancer	C56.9	183.0

Comments

ovarian cancer evaluate for efficacy of chemo, compare to prior

Order Questions

Question	Answer	Comment
Exam reason	ovarian cancer evaluate for efficacy of chemo, compare to prior	
Note: Enter reason for exam		
pregnant	No	
Does the patient require sedation/anesthesia?	No	
recon ct	Yes	

Appointments for this Order

(Resource) +1489 Eccc Rad Ct

Process Instructions

Contrast Allergy:

Prednisone administered, 50mg, 13 hours, 7 hours and 1 hour prior to exam.
Benadryl administered, 50mg, 1 hour prior to exam.

If the GFR <60, please click on hyperlink titled, "Parameters for CT Contrast Administration" (located in the REFERENCE LINK) for proper patient preparation prior to order completion

No Solid Food for 6 hours prior to procedure and no clear liquids for 2 hours prior to procedure. If requiring procedure for today, please make patient NPO now.

Creatinine/BUN/PT/INR/Platelet Count required within this hospitalization for an inpatient/ labs within 90 days for an outpatient.

All patients aged 60 or over require current labs within the past 30 days.

Pediatric patients 5 and under and some older children with certain issues may require sedation to remain still for the exam. Please mark "yes" in these scenarios."

If Questions-please call

Collection Information

Specimen ID:

Collected: +1489

NPN ID:

Referring Agency:

Verbal Order Info

[page 16 of 50]
Action	Created on	Order Mode	Entered by	Responsible Provider	Signed by	Signed on
Ordering		Verbal with readback		MD		+1489

Associated Reports

View Encounter

Priority and Order Details

Collection Information

External References

What if I can't find the structured indication I want?
And, other FAQ's.

Parameters for CT Contrast Administration

[page 17 of 50]
CT CHEST W CONTRAST

Status **Final result**

Procedure ID: [REDACTED]

Images on Full PACS (Carestream)

Show images for CT CHEST W CONTRAST

Images on PACS Light (VueMotion)

Show images for CT CHEST W CONTRAST

Images on PACS Light (External [REDACTED] Provider)

Show images for CT CHEST W CONTRAST

Study Result

Impression:

1. Status post right middle lobe wedge resection with expected soft tissue thickening along the suture line.
2. No lymphadenopathy or new pulmonary nodules.

[REDACTED] MD
Attending Physician

Exam: CT thorax with IV contrast

Clinical indication: ovarian cancer, interval interruption of chemo for surgery (lung mass) evaluate for presence of ovarian cancer.

Technique: Spiral CT was obtained from the jugular notch through the posterior costophrenic recess with 100 cc of Omnipaque 350 intravenous contrast medium. No immediate complications were noted. Coronal and sagittal reformats were performed by a technologist.

Comparison: [REDACTED] +1489

Findings:

Chest

Lungs: Status post right middle lobe wedge resection with expected soft tissue thickening along the suture line. Lungs are clear. No evidence of consolidation or pneumothorax. No suspicious pulmonary nodules.

Pleura: No pleural effusion or focal pleural lesion.

Axilla: No adenopathy

Mediastinum: The heart is normal in size. No pericardial effusion. No pathologic mediastinal or hilar adenopathy. The great vessels appear normal.

Upper Abdomen:

Please see separate dictation for CT of the abdomen.

[page 18 of 50]
Bones:

No evidence of fracture, dislocation, or aggressive osseous abnormality.

Imaging

CT CHEST W CONTRAST (Order # [REDACTED]) on [REDACTED] - Imaging Information

+1608

Result History

CT CHEST W CONTRAST (Order # [REDACTED]) on [REDACTED] - Order Result History Report

+1609

Imaging Information

Exam Information

Performed Procedure

CT CHEST W CONTRAST

Study Status

Final

Begin Time

End Time

+1608

+1608

Staff Information

Technologist

Transcriptionist

Assigned Physician(s)

Assigned Pool(s)

N/A

N/A

N/A

Verification Information

Signed By

Signed On

Marked as Prelim By

Marked as Prelim On

+1609

Read By

Read

Date

Signed By

Signed

Date/Time

Phone

Pager

+1608

Radiology Faculty Web Page

Radiology Faculty Web Page

External Result Report

External Result Report

AM +1613

AM +1611

Reason For Exam

ovarian cancer, interval interruption of chemo for surgery (lung mass) evaluate for presence of ovarian cancer

Dx: Ovarian cancer [REDACTED]

Diagnosis

Codes

Comments

[page 19 of 50]
Malignant neoplasm of ovary

Associated Diagnoses

Ovarian cancer

Other Encounter Related Information

Encounter Charges

CT CHEST W CONTRAST (Order # [REDACTED]) Imaging

+1608 Date [REDACTED] Department Radiology - CT Scan Released By [REDACTED]
Authorizing [REDACTED]

Procedure ID: [REDACTED]

Link to CPT Codes

CPT Codes

Order Information

Order Date/Time

+1608

Release Date/Time

+1608

PM

Start Date/Time

+1608

End Date/Time

None

Order Details

Frequency

None

Duration

1 occurrence

Priority

Routine

Order Class

Ancillary Performed

Order Providers

Authorizing
ProviderEncounter
Provider

Billing Provider

Reprint Imaging Requisition

CT CHEST W CONTRAST (Order # [REDACTED])
on [REDACTED] +1608

Original Order

Ordered On

+1581

Ordered By

Reason For Exam

ovarian cancer, interval interruption of chemo for surgery (lung mass) evaluate for presence of ovarian cancer

Dx: Ovarian cancer [REDACTED]

Associated Diagnoses

Ovarian cancer

ICD-10-CM
C56.9ICD-9-CM
183.0

Comments

ovarian cancer, interval interruption of chemo for surgery (lung mass) evaluate for presence of ovarian cancer.

[page 20 of 50]
Order Questions

Question	Answer	Comment
Exam reason	ovarian cancer, interval interruption of chemo for surgery (lung mass) evaluate for presence of ovarian cancer	
Note: Enter reason for exam		
pregnant	No	
Does the patient require sedation/anesthesia?	No	
recon ct	Yes	

Appointments for this Order

+1608	(Resource)	
-------	------------	--

Process Instructions

Contrast Allergy:

Prednisone administered, 50mg, 13 hours, 7 hours and 1 hour prior to exam.

Benadryl administered, 50mg, 1 hour prior to exam.

If the GFR <60, please click on hyperlink titled, "Parameters for CT Contrast Administration" (located in the REFERENCE LINK) for proper patient preparation prior to order completion

No Solid Food for 6 hours prior to procedure and no clear liquids for 2 hours prior to procedure. If requiring procedure for today, please make patient NPO now.

Creatinine/BUN/PT/INR/Platelet Count required within this hospitalization for an inpatient/ labs within 90 days for an outpatient.

All patients aged 60 or over require current labs within the past 30 days.

Pediatric patients 5 and under and some older children with certain issues may require sedation to remain still for the exam. Please mark "yes" in these scenarios."

If Questions-please call

Collection Information

Specimen ID	
Collected	+1608
NPN ID	
Resulting Agency	

Verbal Order Info

Action	Created on	Order Mode	Entered by	Responsible Provider	Signed by	Signed on
Ordering		Verbal with readback		MD		+1608

Patient Information

Patient Name	Sex	DOB	Test
--------------	-----	-----	------

[page 21 of 50]
Associated Reports

View Encounter

Priority and Order Details

Collection Information

External References

What if I can't find the structured indication I want?

And, other FAQ's.

Parameters for CT Contrast Administration

[page 22 of 50]
Progress Notes Date of Service: [REDACTED] +1643

[REDACTED] MD
Obstetrics & Gynecology

REASON FOR VISIT: Followup for ovarian cancer

[REDACTED] female with a history of stage IIIC ovarian serous carcinoma with clear cell features who is status post TAH/BSO, omentectomy, splenectomy, and optimal tumor debulking in [REDACTED]. Her postoperative course was complicated by pulmonary embolism as well as MRSA infection at her port site. She is on chronic anticoagulation (Fragmin). Postoperatively, the patient was started on intraperitoneal chemotherapy; however, she progressed after 3 cycles and was changed to IV cisplatin and gemcitabine. Treatment was complicated by worsening thromboembolic disease on Coumadin as well as suspected bacterial endocarditis, which required prolonged IV antibiotic treatment. In [REDACTED] after progression on IV cisplatin and gemcitabine the patient was changed to Doxil and continued to progress after 2 cycles. She was then started on single agent Avastin and has now received over 50 cycles of this treatment with sustained partial response and very little toxicity, other than proteinuria and mild hypertension for which she's followed by Nephrology at [REDACTED] (she will see them in [REDACTED]).

+1512 On [REDACTED] she underwent core biopsy of lung nodule (this had grown on CT from 3mm to 16mm over time). Pathology returned as epithelioid and spindle cells and mild atypia and bland spindle cell proliferation suggestive of inflammatory myofibroblastic tumor. (NO METASTATIC OVARIAN CARCINOMA). She is seeing [REDACTED] (thoracic surgery) today.

She presents today for discussion of treatment planning.

INTERVAL HISTORY:

The patient feels well today and she denies any complaints. The patient did have a infection of her incision from the VATS resection which resolved with Keflex. No major weight changes. She denies any issues including GI distress, nausea, vomiting, constipation, diarrhea, changes in her bowels or bladder, shortness of breath, abdominal bloating, pain, or vaginal bleeding. She feels like her left lower extremity is always larger than her right. The patient has been off Fragmin since [REDACTED] of this year.

Her past medical and surgical histories were reviewed and updated as appropriate in Epic.

Medications:

1. Lisinopril 40 mg daily

Allergies:

No Known Allergies

REVIEW OF SYSTEMS: Review of systems is negative x10 other than that noted above

[page 23 of 50]
PHYSICAL EXAM

BP 117/63 | Pulse 75 | Temp(Src) 36.7 °C (98.1 °F) (Oral) | Resp 18 | Ht 1.72 m (5' 7.72") | Wt 109.226 kg (240 lb 12.8 oz) | BMI 36.92 kg/m2 | SpO2 97%

Wt Readings from Last 3 Encounters:

+1643 109.226 kg (240 lb 12.8 oz)
+1559 108.41 kg (239 lb)
+1544 110.8 kg (244 lb 4.3 oz)

PS=0

General: No acute distress, pleasant female. Eyebrows tattooed.

Head: normocephalic, atraumatic. Mucous membranes moist.

Neck: Supple.

Lymphatics: no adenopathy in head, neck, axilla bilaterally

Heart: Regular rate and rhythm.

Lungs: Clear to auscultation bilaterally.

Abdomen: Soft, non-distended, non-tender. Well healed vertical midline incision.

Pelvic: deferred (

Extremities: symmetric, nontender. Trace edema at ankles, stable per patient report. LLE > RLE.

LABS:

Lab Results

Component	Value
WBC	13.32*
NEUTOPHILPCT	49.6
NEUTROABS	6.59
LYMPHOPCT	32.4
LYMPHSABS	4.32
HGB	14.5
HCT	44.1
PLT	361
ALT	23
AST	26
NA	141
K	4.0
CREATININE	0.7
BUN	12
INR	1.0
CA125	6

Date

+1608

Ovarian Cancer Antigen 125

Date	Value	Range	Status
+1608	6	0 - 21 U/mL	Final
+1531	10	0 - 21 U/mL	Final
+1489	6	0 - 21 U/mL	Final

Res

Ref. Range					
Protein, Ur	Latest Range: <140 mg/L	4161.0 (H)	6149.0 (H)	8149.0 (H)	0.55

+1342

+1384

+1447

+1468

+1468

[page 24 of 50]
Imaging [REDACTED] +1608

Impression:

Chest:

1. Status post right middle lobe wedge resection with expected soft tissue thickening along the suture line.
2. No lymphadenopathy or new pulmonary nodules.

Abd/Pelvis:

1. Stable appearance of abdominal and pelvic lymphadenopathy, and peritoneal implants as described above. No definite new metastatic lesions are identified.
2. Status post cholecystectomy and splenectomy.
3. Status post total abdominal hysterectomy and bilateral salpingo-oophorectomy.

ASSESSMENT AND PLAN:

This is a [REDACTED] female with platinum resistant stage IIIC ovarian serous carcinoma with clear cell features, here for treatment planning discussion.

1. Ovarian Carcinoma:

- The patient will have baseline lab work done today.
- Plan for her to return in 10 weeks from her last CT and have an appointment with Dr. [REDACTED] to decide on the next step of her treatment plan

2. Proteinuria:

- Appreciate Nephrology input.
- We will have the patient collect a 24 hour urine protein to turn in at her next visit.
- Continue lisinopril

3. Hypercoagulability:

- Patient self-discontinued her Fragmin and has not had a recurrent thrombotic event. Will leave of anticoagulation. Patient has an IVC filter in place.

4. Lung nodule

- Recovering well from her pulmonary surgery. [REDACTED] scan shows no pulmonary disease.
- Has follow up with thoracic surgery

+1608

[REDACTED]
Gynecologic Oncology Fellow

I have personally interviewed and examined the patient. I have reviewed the provider's history, physical exam, assessment and management plans. I concur with or have edited all elements of the provider's note.

[page 25 of 50]
[Redacted]

[Redacted]
Protocol 9671

Encounter Date: [Redacted]
+1643

[Redacted]

Office Visit on

[Redacted]

+1643

Revision History

[page 26 of 50]
Result Date - [REDACTED] +1517

Component Results

Component Value

Pathology Report (NOTE)

CYTOLOGY REPORT

Case No: [REDACTED]

Date Collected: [REDACTED]

Date Received: [REDACTED]

+1512

+1512

DIAGNOSIS:

LUNG, RIGHT LOWER LOBE:

EPITHELIOID AND SPINDLE CELLS WITH MILD ATYPIA.

LUNG, RIGHT LOWER LOBE CORE BIOPSY.

BLAND SPINDLE CELL PROLIFERATION. (See note.)

Note:

Microscopically within the core biopsy there is a proliferation of bland spindle cells set in a myxoid background. Scattered plasma cells and lymphocytes are seen throughout the lesion.

Immunohistochemical stains for IgG and IgG4 are performed, and do not show an increased level of IgG4 plasma cells. Immunohistochemical stains for ALK1 is negative, while a SMA immunohistochemical stain highlights only background blood vessels.

In summary, the morphologic features of this tumor are most suggestive of an inflammatory myofibroblastic tumor. There is no evidence of metastatic ovarian carcinoma present.

By my electronic signature affixed below, I affirm that I have reviewed this report and all pathologic materials + information pertaining to this case with the resident/fellow physicians listed, and that I am personally responsible for all stated diagnoses in this report.

+1517

[page 27 of 50]
Referred by:

Copy To:

Specimen Source:

1: LUNG, RIGHT LOWER LOBE

Core needle biopsy slides x 1, Unstained slide for immuno
- recut x 5,

Core needle biopsy slides x 1, Smears made x 3, ALX-1 x 1,
SMOOTH MUSCLE ACTIN

(SP) x 1, IgG4 x 1, IgG IHC x 1, NEGATIVE (SP) x 1, RECUT x 1

Gross Description

DOCUMENTATION OF FNA PERFORMANCE

Performed By:

Aspiration Site(s): Lung, right lower lobe.

Needle Passes: 1

Needle Rinses: None

Fluid Obtained: None

Description/Comment: Lung sampled using capillary action.

Complications: None

Preliminary Assessment: Lung, right lower lobe. Atypical
cells present, core

biopsy requested.

Evaluated by:

Results communicated to on +1512

Core needle biopsy: Multiple tissue fragment(s) measuring 4
mm x 3 mm in
aggregate.

Clinical History:

History ovarian ca; s/p resection/debulking chemo iv
and
intraperitoneal.

Lab and Collection

Cytology Fine Needle Aspriate (FNA) on +1512

on AM

MD on AM

[page 28 of 50]
Cytology Fine Needle Aspriate (FNA)

+1517

Result Information

Status
Final result (Collected: [REDACTED] PM)
Provider Status
Reviewed
+1513

View SmartLink Info

Cytology Fine Needle Aspriate (FNA) (Order [REDACTED] on [REDACTED] +1513

Results Routing Details for Order: [REDACTED]	
Outcome:	Routed using routing scheme
Routing Scheme Used:	[REDACTED] ROUTING [REDACTED]
Routing Scheme Line:	[REDACTED]
Resulting User:	[REDACTED]
Routing Instant:	[REDACTED] PM +1517
Comments:	Added members of Care Team to recipient list#ptDat, eptDat, routingDAT respectively [REDACTED]
Current Status:	Routing Complete
Status History:	Result contact created [REDACTED] PM +1517
	Routing started [REDACTED] PM +1517
	Routing Complete [REDACTED] PM +1517
In Basket Sent:	Message ID: [REDACTED]
	Responsible: Yes
	Provider ID: [REDACTED] (provider defined by Results Routing)
	Result routed to linked user [REDACTED] using In Basket
In Basket Sent:	Message ID: [REDACTED]
	Responsible: Yes
	Provider ID: [REDACTED] (provider defined by Results Routing)
	Result routed to linked user [REDACTED] using In Basket
In Basket Sent:	Message ID: [REDACTED] Recipients:
	[REDACTED]
	Responsible: No
	Recipient added as CC recipient [REDACTED]

Results Tracking

Order Description	Order ID	Instant of Order	Order Class
CYTOLOGY FINE NEEDLE ASPRIATE (FNA)	[REDACTED]	[REDACTED] PM +1512	Unit Collect

Ordering User	Authorizing Provider	Procedure	Proc. Category	Abnormal?
[REDACTED]	[REDACTED]	CYTOLOGY FINE NEEDLE ASPRIATE (FNA) [REDACTED]	PATHOLOGY/CYTOLOGY ORDERABLES [8]	

Encounter Provider	Encounter Department	Encounter Date	Encounter Type	ASN
[REDACTED]	[REDACTED]	[REDACTED] +1512	Hospital Encounter	[REDACTED]

Results Routing Outcome	Schema Used	Line	Results Routing User	Result Date	Result Time
Routed using routing scheme	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED] PM +1517

[page 29 of 50]
Added members of Care Team to recipient list#ptDat, eptDat, routingDAT respectively [REDACTED] #

Routing Information

This letter was not routed.

Cytology Fine Needle Aspriate (FNA) (Order

+1512 Date: [REDACTED] Department: Radiology - CT Scan Released By: [REDACTED] Lab (auto-released)
Authorizing: [REDACTED] MD

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]
+1512	+1512	+1512	+1512
Order Details			
Frequency	Duration	Priority	Order Class
ONE TIME	1 occurrence	Routine	Unit Collect

Order Providers

Authorizing Provider: [REDACTED] Encounter Provider: [REDACTED] Reprint Outpatient Order Requisition
Cytology Fine Needle Aspriate (FNA) (Order +1512)

Reprint Inpatient Order Requisition
Cytology Fine Needle Aspriate (FNA) (Order [REDACTED])

Original Order

Ordered On: [REDACTED] Ordered By: [REDACTED] Order #: [REDACTED]

Comments

Hx ovarian ca; s/p resection/debulking [REDACTED] chemo iv and intraperitoneal

Order Questions

Question	Answer	Comment
Enter Source:	lung	

Lab Collection Information

Collected: [REDACTED] +1512
NPN ID: [REDACTED]

Acknowledgement Info

For	At	Acknowledged By	Acknowledged On
Placing Order	[REDACTED]	[REDACTED]	[REDACTED]

Verbal Order Info

Action	Created on	Order Mode	Entered by	Responsible Provider	Signed by	Signed on
	+1512					+1512

[page 30 of 50]
Ordering

+1512

Written order

Signature Not
Required

Patient Information

Additional Information

[Associated Reports](#)

[External References](#)

[View Encounter](#)

[Lab Manual](#)

[Priority and Order Details](#)

[Collection Information](#)

No order transmittal information available.

Order may not have completed order transmittal.

[page 31 of 50]
Result Date - [REDACTED] +1545

Component Results

Component Value

Pathology Report (NOTE)

SURGICAL PATHOLOGY REPORT [REDACTED]

Date Collected: [REDACTED]

Date Received: [REDACTED]

+1543

DIAGNOSIS:

LUNG, RIGHT MIDDLE LOBE, WEDGE RESECTION:

INFLAMMATORY MYOFIBROBLASTIC TUMOR. (See note.)

88307, 88342

Note: An immunohistochemical stain for ALK-1 is non-reactive.

This case was reviewed at the surgical pathology consensus conference and the group agreed with the diagnosis.

**Electronically Signed Out By [REDACTED] on

+1545

By my electronic signature affixed below, I affirm that I have reviewed this report and all pathologic materials + information pertaining to this case with the resident/fellow physicians listed, and that I am personally responsible for all stated diagnoses in this report.

+1545

Referred by:

Tissue:

1: RT MIDDLE LOBE WEDGR

[page 32 of 50]
Clinical Diagnosis:

Lung nodule right. History of breast and ovarian carcinoma.
ICD-9 code is not provided.

Gross Description:

The specimen is received in one part.

Part one is received fresh, labeled with the patient's name

and

medical record number and designated "right middle lobe wedge".

The specimen consists of a 4.1 g, 5.4 x 1.4 x 1.3 cm wedge of lung. The

external surface is red and glistening. The staple line is removed and the

underlying surface inked blue. Sectioning reveals a 1.5 x 1.5 x 1.2 cm

white/tan well-circumscribed nodule that abuts the blue-inked margin but

grossly appears completely excised. A section is submitted for frozen section

diagnosis which reads, "FS1A: Lung, right middle lobe, wedge resection:

Spindle cell and inflammatory lesion, consistent with inflammatory

myofibroblastic tumor". The interpretation was rendered at

a.m. to at the scope. The frozen section control is submitted in

cassette 1A. An additional representative section of the lesion and a

representative section of uninvolved lung are submitted in cassette 1B.

CASSETTE SUMMARY

Rep, 2 blocks

Total slides: 2 E-E

Total blocks: 2

+1544

Lab and Collection

Surgical Pathology Biopsy/Other of +1543

+1545

+1545

[page 33 of 50]
Surgical Pathology Biopsy/Other

Result Information

Status [REDACTED] Provider Status
Final result [REDACTED] Reviewed
[REDACTED] +1543

View SmartLink Info

Surgical Pathology Biopsy/Other [REDACTED] +1543

Results Routing Details for Order: [REDACTED]	
Outcome:	Routed using routing scheme
Routing Scheme Used:	[REDACTED]
Routing Scheme Line:	5
Resulting User:	[REDACTED]
Routing Instant:	+1545
Comments:	Added members of Care Team to recipient list#ptDat, eptDat, routingDAT respectively. [REDACTED]
Current Status:	Routing Complete
Status History:	Result contact created [REDACTED] +1545
	Routing started [REDACTED] +1545
	Routing Complete [REDACTED] +1545
In Basket Sent:	Message ID [REDACTED] Recipients: [REDACTED]
	Responsible: Yes
	Provider ID: [REDACTED] (provider defined by Results Routing)
	Result routed to linked user [REDACTED] using In Basket
In Basket Sent:	Message ID: [REDACTED] Recipients: [REDACTED]
	Responsible: Yes
	Provider ID: [REDACTED] (provider defined by Results Routing)
	Result routed to linked user [REDACTED] using In Basket
In Basket Sent:	Message ID: [REDACTED] Recipients: [REDACTED]
	Responsible: No
	Recipient added as CC recipient [REDACTED]

Results Tracking

Order Description	Order ID	Instant of Order	Order Class
SURGICAL PATHOLOGY BIOPSY/OTHER	[REDACTED]	[REDACTED] +1543	External System
Ordering User	Authorizing Provider	Procedure	Proc. Category
Lab Results Inbound	[REDACTED]	SURGICAL PATHOLOGY BIOPSY/OTHER	PATHOLOGY/CYTOLOGY ORDERABLES [8]
Encounter Provider	Encounter Department	Encounter Date	Encounter Type
[REDACTED]	[REDACTED]	[REDACTED] +1530	Hospital Encounter
Results Routing Outcome	Scheme Used	Encounter Routing User	Result Date
	5	[REDACTED]	Result Time
			[REDACTED] +1545

[page 34 of 50]
Routed using routing
scheme

Lab Results Inbound Edi
[EDILABIM]

Added members of Care Team to recipient list#ptDat, eptDat, routingDAT respectively:

Routing Information

This letter was not routed.

Surgical Pathology Biopsy/Other (Order

Date Department Released By: (auto-released) Authorizing

Lab

+1545

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time

Order Details

+1543

+1543

+1543

+1543

Frequency	Duration	Priority	Order Class
ONCE	1 occurrence	Routine	External System

Order Providers

Authorizing Provider	Encounter Provider

Reprint Outpatient Order Requisition

Surgical Pathology Biopsy/Other (Order

+1543

Reprint Inpatient Order Requisition

Surgical Pathology Biopsy/Other (Order

+1543

Original Order

Ordered On	Ordered By	Order #

+1543

Lab Collection Information

Collected	NPN ID

+1543

Additional Information

Associated Reports	External References
View Encounter	Lab Manual
Priority and Order Details	
Collection Information	

No order transmittal information available.

[page 35 of 50]
Order may not have completed order transmittal.

[page 36 of 50]
CT CHEST ABDOMEN PELVIS W CONTRAST

Status: Final result

Procedure ID: [REDACTED]

Images on Full PACS (Carestream)

Show images for CT CHEST ABDOMEN PELVIS W CONTRAST

Images on PACS Light (VueMotion)

Show images for CT CHEST ABDOMEN PELVIS W CONTRAST

Images on PACS Light (External [REDACTED] Provider)

Show images for CT CHEST ABDOMEN PELVIS W CONTRAST

Study Result**SIGNED FINAL REPORT**

PT ACCT NO: [REDACTED]

ORDER NO: [REDACTED]

EXAMINATION:

CBI [REDACTED] CT CHEST ABD PELVIS W CON EXAM DT/TIME: [REDACTED] +292

Accession No: [REDACTED]

CLINICAL DATA: [REDACTED] with ovarian cancer on chemo for eval of response,

FULL RESULT: CT chest ,abdomen and pelvis with contrast, [REDACTED] +292

Comparison: Multiple prior studies including a CT dated [REDACTED] +243

Clinical indication: [REDACTED] female with h/o ovarian cancer with clear cell features.

Technique: Helically acquired contiguous 5 mm axial images were obtained from the thoracic inlet to the pubic symphysis with oral contrast and 100 cc of Omnipaque intravenous contrast.

Findings:**Chest:**

Extrathoracic findings: No enlarged axillary and supraclavicular lymph nodes. Thyroid is unremarkable.

Lungs/Pleura: Interval decreased in size in the multiple prior described pulmonary nodules, as follows:

1. The prior noted 2.5 cm nodule in the left upper lobe is not identified in the present study (on image 4-57) . 2. Unchanged 4mm pulmonary nodule in the right upper lobe (on image 4 -50). 3.The 11mm pulmonary nodule in the azygoesophageal recess noted (on image 4-62) in the prior study has decreased in size, currently it measures 6.5 mm versus 11 mm in the prior study. 4. A 6mm nodule adjacent to a vessel in the right upper lobe on image 4-69, is unchanged. 5. The prior noted 7.5 mm nodule in the left upper lobe on image 4-81, in the today's study measures 2.5 mm. 6. The prior noted lingular nodes on images 4-93 and 4-102 are unchanged. 7. The 13 mm nodule adjacent to the right hemidiaphragm is not seen in the present study. No new pulmonary nodules. No pleural effusion or pneumothorax.

Mediastinum/Hila: Interval increased in size in the prior described enlarged mediastinal and hilar lymph nodes as follows: 1. There is a 1.8 cm right paratracheal adenopathy (on image 2-13), that in the prior study measured 8 mm.

2. There is a 1.3 cm pretracheal adenopathy (on image 2-16) that in the prior measured 8 mm.

[page 37 of 50]
CT CHEST ABDOMEN PELVIS W CONTRAST

Status: Final result

Procedure ID: [REDACTED]

Images on Full PACS (Carestream)

Show images for CT CHEST ABDOMEN PELVIS W CONTRAST

Images on PACS Light (VueMotion)

Show images for CT CHEST ABDOMEN PELVIS W CONTRAST

Images on PACS Light (External [REDACTED] Provider)

Show images for CT CHEST ABDOMEN PELVIS W CONTRAST

Study Result**SIGNED FINAL REPORT**

PT ACCT NO: [REDACTED]

ORDER NO: [REDACTED]

EXAMINATION:

CBI [REDACTED] CT CHEST ABD PELVIS W CON EXAM DT/TIME: [REDACTED] +243

Accession No: [REDACTED]

CLINICAL DATA: ovarian cancer, s/p surgery, IP chemo, systemic chemo, compare with prior CT for response to tx.,

FULL RESULT: Indication: Ovarian cancer, followup

Comparison: Multiple priors most recent [REDACTED] +182

Procedure: Helical slices were made from the thoracic inlet through the symphysis pubis. Oral contrast was given prior to scanning. 100 cc Omnipaque 350 I.V. contrast was given.

Chest Findings:

Lungs/Pleura: Numerous pulmonary nodules consistent with metastases are again visualized with interval enlargement of most indicating disease progression. Largest nodules include left upper lobe elongated soft tissue mass measuring 27 x 12 mm in the axial plane (4-57) with broad involvement of the adjacent mediastinal pleura, increased from 17 x 12 mm on the prior by my measurements today; spherical 5.7 mm right upper lobe nodule is minimally decreased in size, previously 7 mm (4-50 today's exam versus 4-51 of the prior); posteromedial right upper lobe nodule abutting the pleura of the azygosoesophageal recess measures 11 mm, compared to 5.5 mm on the prior (4-62 today's exam); 3.5 mm nodule adjacent to a vessel in the more inferior posterior right upper lobe (4-69) increased from 2.5 mm; anterior/inferior left upper lobe 7.5 mm nodule (4-81) and previously 3 mm; 5 mm lingular nodule (4-93) previously 3 mm; and 4.7 mm lateral left midlung subpleural nodule (4-104) increased from 3 mm on the prior; a 13 mm nodule adjacent to the right hemidiaphragm (4-126) is grossly unchanged, and may be arising from the liver or the lung/pleura. No focal parenchymal consolidation. No pleural effusions.

Mediastinum: No evidence of mediastinal masses. Hilar adenopathy as below.

Cardiovascular: Grossly normal appearance of the heart, thoracic aorta and great vessels. No pericardial effusion.

Lymphadenopathy: Interval worsening left hilar adenopathy, with conglomerate nodal mass measuring approximately 38 x 33 mm (images 2-20 through 22) increased from 31 x 26 mm on the prior. A separate left

[page 38 of 50]
infrahilar node is also increased, measuring 16 x 16 mm (2-23) previously subcentimeter. On the right, a prominent hilar node measures 10 mm in short axis, (2-20) previously subcentimeter. No interval enlargement of right lower paratracheal node measuring 11 mm in short axis (2-15) previously less than 6 mm.

Abdomen Findings:

Liver/Biliary System: Multiple hypodense, mildly ring-enhancing liver metastases, many of which have increased in size since prior.

Approximately 15 to 20 total lesions are seen, some of the largest including: 21 mm right lobe (2-36) previous 13 mm; just posterior to this 20 mm right dome lesion (2-37) not previously well seen; posterior segment 2 18 mm lesion (2-41) previously poorly defined and subcentimeter; subcapsular partially exophytic 22 mm lesion medial segment 5 (2-61) previously measuring approximately 18 mm; 12 mm anterior segment 5 (2-62) previously 6 mm; multiple additional subcentimeter lesions are new or increased. Additionally, there is a triangular heterogeneously hypodense lesion posterior to the IVC which appears to be intimately associated with the adrenal gland and measures 19 mm in greatest axial dimension, unchanged (2-47), this may represent a liver or adrenal metastasis. Gallbladder surgically absent. The bile ducts do not appear dilated.

Pancreas/Spleen: The pancreas enhance homogeneously without abnormality. The spleen is not visualized, presumably surgically absent.

Kidneys/Adrenals/Retroperitoneum: Normal left adrenal gland. As above, 19 mm soft tissue nodule between the superior aspect of the right adrenal gland and IVC may arise from the adrenal or the liver. Otherwise the right adrenal is normal in appearance. The kidneys are symmetric in size and with no hydronephrosis or evidence of mass. Normal symmetric enhancement. Retroperitoneal adenopathy as described window.

Aorta/Vessels: Infrarenal IVC filter is again noted, with thrombus within the upstream IVC and iliac vessels. The abdominal aorta, major arterial structures, portal vein and hepatic veins appear patent and normal in caliber.

Bowel: Grossly normal appearance of the stomach, duodenum, abdominal loops small bowel and colon.

Lymphatics/Fluid: Peritoneal carcinomatosis with implants and adenopathy increased in comparison to the prior exam. Some of largest masses include right periaortic rounded lesion measuring 35 x 38 mm in the axial plane (2-72) which displaces the third portion of the duodenum anteriorly, previously measuring 31 x 32 mm by my measurements today, however, more dense internally on that exam raising the question of necrosis/liquefaction contributing to the interval enlargement; more caudal to this, there is confluent left periaortic adenopathy which has slightly increased since prior, and into the superior aspect which measures a maximum of 32 x 30 mm (2-76) compared to 26 x 26 mm prior; at the same level, soft tissue nodule at the inferior aspect of the right periaortic mass measures 20 x 20 mm (2-77) increased from 11 x 13 mm; at the porta hepatis, there is interval enlargement of the nodal mass measuring 45 x 26 mm in the axial plane (2-56) previously 33 x 13 mm; adjacent to the undersurface of the left lobe the liver, 35 x 21 mm nodule (2-54) has increased from 25 x 13 mm; extensive peritoneal implants in the left upper quadrant are increased, including 47 x 35 mm abutting the gastric wall (2-43) previously 40 x 27 mm; posterior to this 25 x 23 mm nodule that previously 25 x 17 mm; more inferiorly along the

[page 39 of 50]
splenic flexure, 30 x 21 mm implant previously 27 x 19 mm; multiple additional node/implants are seen, unchanged or slightly increased. There is no free fluid or loculated fluid collection identified.

Pelvis Findings: Postoperative changes of TAH/BSO. Unchanged enhancing nodule abutting the right vaginal cuff measuring 15 mm (2-103). 16mm left iliac node (2-93) has increased from 9 mm on the prior. Rounded 12 mm right iliac node (2-97) has increased from 7 mm on the prior. 12 x 9 mm nodule abutting the sigmoid colon and bladder (2-103) slight increased from prior 10 x 7 mm. Probably partially occlusive clot is again seen within the inferior vena cava just above the bifurcation extending into the bilateral common iliac veins, perhaps progressing from prior. Within the overlying soft tissues, there is unchanged sharply defined 13 mm nodule anterior left abdominal wall underlying skin.

Bony structures: No evidence of acute or aggressive osseous lesions.

IMPRESSION:

Chest:

1. Multiple pulmonary nodules, the majority of which have enlarged since prior consistent with disease progression. See above for details.
2. Worsening left hilar adenopathy, again consistent with disease progression. Minimal increase in borderline 10 mm right hilar node.

Abdomen:

1. Interval enlargement of multiple liver metastases as described in detail above consistent with disease progression.
2. Additional lesion which may arise from the liver or superior aspect of the right adrenal gland is unchanged.
3. Interval worsening of disease throughout the abdomen, with numerous intraperitoneal implants and retroperitoneal adenopathy as described above.
4. Nonocclusive thrombus within the IVC and iliac veins in the setting of IVC filter. This may have slightly progressed.

Pelvis:

1. Slight worsening of implants/nodes in the pelvis as described above, consistent with disease progression.

Attending Physician, Radiology

TECHNOLOGIST:

READING MD:

DATE/TIME:

+243

SIGNING MD:

DATE/TIME:

+243

THIS DOCUMENT WAS SIGNED ELECTRONICALLY

A COPY OF THIS DOCUMENT IS ON-LINE IN THE CARECAST ARCHIVE SYSTEM. BY ELECTRONICALLY SIGNING THIS REPORT, I THE SIGNING PHYSICIAN ATTEST THAT I HAVE PERSONALLY REVIEWED THE FILMS FOR THE ABOVE EXAMINATION(S) AND AGREE WITH THE FINDING(S) AS DOCUMENTED ABOVE.

Imaging

CT CHEST ABDOMEN PELVIS W CONTRAST (Order XXXXXXXXXX imaging Information

+243

Imaging Information

Exam Information

Performed Procedure	Study Status	Begin Time	End Time
CT CHEST ABDOMEN PELVIS W CONTRAST	Final		N/A

[page 40 of 50]
+243

Staff Information

Technologist N/A	Transcriptionist N/A	Assigned Physician(s) N/A	Assigned Pool(s) N/A
---------------------	-------------------------	------------------------------	-------------------------

Verification Information

Signed By [REDACTED]	Signed On [REDACTED] +390
-------------------------	------------------------------

Read By

Read [REDACTED]	Date [REDACTED] +390
--------------------	-------------------------

Signed By

Signed [REDACTED]	Date/Time [REDACTED]	Phone [REDACTED]	Pager [REDACTED]
----------------------	-------------------------	---------------------	---------------------

Radiology Faculty Web Page

+390

Radiology Faculty Web Page

External Result Report

External Result Report

Reason For Exam

[REDACTED] MALIGN NEOPL OVARY

Other Encounter Related Information

Encounter Charges

CT CHEST ABDOMEN PELVIS W CONTRAST (Order

Date: [REDACTED] +243

Depart: [REDACTED]

Imaging

Order: [REDACTED]

Ordering/Authorizing: [REDACTED]

Procedure ID: [REDACTED]

Link to CPT Codes

CPT Codes

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
-----------------	-------------------	-----------------	---------------

+243

Order Details

Frequency None	Duration None	Priority Early	Order Class Normal
-------------------	------------------	-------------------	-----------------------

Order Providers

Authorizing Provider
[REDACTED]

Reprint Imaging Requisition

CT CHEST ABDOMEN PELVIS W CONTRAST

+243

[page 41 of 50]
Encounter Provider

Billing Provider

Reason For Exam

MALIGN NEOPL OVARY

Collection Information

Collected:

Patient Information +243

Additional Information

Associated Reports

View Encounter

Priority and Order Details

Collection Information.

[page 42 of 50]
CT ABDOMEN PELVIS W CONTRAST

Status: Final result

Procedure ID [REDACTED]

Images on Full PACS (Carestream)

Show images for CT ABDOMEN PELVIS W CONTRAST

Images on PACS Light (VueMotion)

Show images for CT ABDOMEN PELVIS W CONTRAST

Images on PACS Light (External) [REDACTED]

Show images for CT ABDOMEN PELVIS W CONTRAST

Study Result**IMPRESSION:**

1. Mixed interval response to therapy. The majority of the mesenteric deposits and lymph nodes are stable in size. A common hepatic lymph node continues to decrease in size however a right middle lobe pulmonary nodule has enlarged.
2. Status post cholecystectomy, splenectomy and TAH/BSO.
3. Bladder wall thickening is likely an inflammatory cystitis, possibly related to intraperitoneal chemotherapy.

[REDACTED]

Examination: CT of the abdomen and pelvis with contrast

Comparison [REDACTED] +1279

Technique: Helically acquired contiguous axial images were obtained from the lung bases to the pubic symphysis with oral contrast material and 100 of Omnipaque 350 IV contrast material. Coronal and sagittal reformats were provided and utilized for interpretation.

Findings:

Thoracic structures are detail on the dedicated chest CT. See this for full detail regarding an enlarging right middle lobe pulmonary nodule, now measuring 14 mm in size.

Abdomen and pelvis:

Overall there's been a mixed interval response to therapy in numerous peritoneal deposits and lymph nodes.

- The only lymph node that decreased in size is a celiac axis node above the pancreas on image 7-22 that measures 10 mm today compared to 15 mm previously
- A right middle lobe pulmonary nodule has increased in size from 5 mm previously to approximately 14 mm today
- Multiple additional mesenteric deposits remain relatively stable in size including a 7 mm deposit in the gallbladder fossa (image 7-33), a 13 mm left subdiaphragmatic deposit (7-17), an 8mm deposit anterior to the stomach (7-17), a 14 mm deposit in the left paracolic gutter (7-41) and a 20 x 14 mm aortocaval lymph node (image 7-42). Morphologically abnormal right external iliac node (image 7-79) and left external iliac lymph node (7-76) are also unchanged.

[page 43 of 50]
The liver is normal in size and density without focal liver lesions. Gallbladder surgically absent. No biliary ductal dilatation. The pancreas is normal in size and a 4 mm hypodensity in the body of the pancreatic parenchyma is unchanged from multiple priors. The spleen is surgically absent. The kidneys and adrenal glands are normal bilaterally. The stomach, and large bowel are normal in caliber. A normal appendix is visualized. No wall thickening or distention. The aorta and IVC are normal in caliber. An infrarenal IVC filter is in place. The uterus is surgically absent. Unremarkable appearance of the vaginal cuff. Bladder is thick walled, likely an inflammatory cystitis. No free fluid. ~+0

A 14 mm soft tissue nodule in the left anterior abdominal wall is stable since [REDACTED] likely a sebaceous cyst and not metastatic disease. No other suspicious soft tissue nodules. The bones are well-mineralized no no aggressive osseous lesions.

Imaging

CT ABDOMEN PELVIS W CONTRAST (Order [REDACTED]) Imaging Information
+1489

Result History

CT ABDOMEN PELVIS W CONTRAST (Order [REDACTED]) Order Result History Report
+1489

Imaging Information

Exam Information

Performed Procedure	Study Status	Begin Time	End Time
CT ABDOMEN PELVIS W CONTRAST	Final	[REDACTED]	[REDACTED]
		+1489	+1489

Staff Information

Technologist	Transcriptionist	Assigned Physician(s)	Assigned Pool(s)
[REDACTED]	N/A	N/A	N/A

Verification Information

Signed By	Signed On	Marked as Prelim By	Marked as Prelim On
[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]
	+1489		

Read By

Read	Date
[REDACTED]	[REDACTED]
	+1489

Signed By

Signed	Date/Time	Phone	Pager
[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]
	+1489		

Radiology Faculty Web Page

Radiology Faculty Web Page

External Result Report

External Result Report

[REDACTED]	+1494
[REDACTED]	+1490

Reason For Exam

ovarian cancer evaluate for efficacy of chemo, compare to prior

[page 44 of 50]
Dx: Ovarian cancer

Diagnosis

Malignant neoplasm of ovary

Associated Diagnoses

Ovarian cancer

Other Encounter Related Information

Encounter Charges

CT ABDOMEN PELVIS W CONTRAST (Order

Imaging

Order

Date: +1489

Department:

Procedure ID:

Link to CPT Codes

CPT Codes

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
Order Details +1489	+1489	+1489	
Frequency	Duration	Priority	Order Class
None	1 occurrence	Routine	Ancillary Performed

Order Providers

Authorizing Provider

Encounter Provider

Billing Provider:

Reprint Imaging Requisition

CT ABDOMEN PELVIS W CONTRAST (Order

+1489

Original Order

Ordered On

Ordered By

+1489

Reason For Exam

ovarian cancer evaluate for efficacy of chemo, compare to prior

Dx: Ovarian cancer

Associated Diagnoses

Ovarian cancer

Comments

ovarian cancer evaluate for efficacy of chemo, compare to prior

Order Questions

Question

Answer

Comment

Exam reason

[page 45 of 50]
protocol # 9671

ovarian cancer
evaluate for efficacy
of chemo, compare
to prior

Note: Enter reason for exam
pregnant

No

Appointments for this Order

+1489

Process Instructions

All cardiac patients: No caffeine after midnight.
Clear liquids only 4 hours prior to exam.

A Creatinine and/or BUN is required within this hospitalization.

If you have done labwork in the last 90 days please bring a copy with you or the number of the doctors
office/hospital in which they were done.

Pediatric patients 5 and under and some older children with certain issues may require sedation to remain
still for the exam. Please mark "yes" in these scenarios."

Collection Information

Collected: +1489

Resulting Agency:

Verbal Order Info

Action
Ordering

Order Mode
Verbal with
readback

Entered by

Responsible
Provider

Signed By

Signed On

+1489

Patient Information

Additional Information

Associated Reports
View Encounter

External References

What if I can't find the structured indication I want?
And, other FAQ's.

Priority and Order Details
Collection Information.

[page 46 of 50]
3. There is a 1.4 cm adenopathy anterior to the aortic pulmonary window (on image 2-17) that in the prior study measured 8 mm. 4. No significant interval changes in the prior described left hilar nodal mass (on image 2-20), currently measures 3.0 x 2.8 cm versus 3.5 x 3.0 cm in the prior study. 5. Interval decreased in size in the left infrahilar node (on image 2-23), now measures 1.2 x 1.0 cm versus 1.6 x 1.6 cm in the prior study.

Trachea is midline and airways without evidence of abnormality.

Heart/Vessels: Heart is normal in size with no pericardial effusion.

Bone: No aggressive osseous lesions.

Abdomen:

Omental/peritoneal surfaces: Slightly decreased in size in the multiple omental and peritoneal implants. The masses abutting the posterior surface of the gastric body and fundus have decreased in size, for example: the prior noted mass on image 2-42, now measures 3.0 cm versus 4.1 cm in the prior study. Unchanged 3.3 cm lesion adjacent to the gastric body on image 2-44.

The Mass posterior to the descendent colon (on image 2-70) currently measures 2.5 x 3.8 versus 3.7 x 3.4 cm in the prior study. Unchanged multiple anterior peritoneal implants seen on image 2-70.

Liver: Again multiple metastatic lesions are noted with the largest in the segment 4 A measuring 2.1 cm. No new metastatic lesions noted.

Intrahepatic and extrahepatic bile ducts are nondilated.

The gallbladder is surgically absent. Pancreas, adrenal glands all appear grossly normal. The prior described 1.9cm soft tissue node arising between the right adrenal and the IVC is not seen in the present study. Spleen is not visualized.

Kidneys: Symmetric in size with no hydronephrosis, calculi or masses.

Bowel: Stomach, small and large bowel all appear grossly normal.

Vessels: Aorta is normal in caliber. IVC filter, unchanged. The prior described partially occlusive clot in the IVC is not seen in the present study.

No intra-abdominal free fluid or free air.

Lymph nodes: The conglomerate of periaortic lymph nodes has decreased in size, now measures 2.6 x 2.4 cm versus 2.9 x 3.0 cm. The aortocaval conglomerate (on image 2-70) is smaller, currently measure 2.7 x 2.8 cm.

There is interval enlargement of the nodal mass at the porta hepatis. It measures 5.1 x 3.2 cm in the today's study versus 4.1 x 2.4 cm previously.

Pelvis:

Status post TAH and BSO.

Bladder is not well distended. Intrapelvic small bowel is normal in caliber. Interval decreased in size in pelvic soft tissue mass abutting the vaginal cuff (on image 2-107), now measures 1.5 cm versus 1.7 cm in the prior study. Unchanged 2.2 cm left iliac node (on image 2-93). Unchanged 1.2 cm right iliac node on image 2-97.

Bones: No acute fractures or destructive bone lesions are identified.

Others: There are several subcutaneous soft tissues lesions with the largest measuring 2.1 x 1.5, likely representing injection sites from chronic heparin therapy.

IMPRESSION:

Chest:

1. Interval decreased in size in the multiple pulmonary nodules, as described above.

2. Interval enlargement in the mediastinal and hilar adenopathies, as

[page 47 of 50]
described above.

Abdomen:

1. No significant changes in the prior described multiple liver metastases as described above with the largest measuring 2.1 cm.
2. Slightly decreased in size in the multiple omental and peritoneal implants, as was described above.
3. Interval resolution of the 1.9cm soft tissue node arising between the right adrenal and the IVC.
4. Interval decreased in size in the prior described periaortic and aortocaval conglomerates of lymph nodes with exception of the one located in the porta hepatis.
5. No intra abdominal ascites.
- 6 Status post cholecystectomy.

Pelvis:

1. Interval improvement in the prior described intrapelvic soft tissues lesions and unchanged enlarged lymph nodes, as described in detailed above.
2. Multiple new subcutaneous nodules in lower anterior abdominal wall likely representing cutaneous injection sites related to heparin therapy. Correlate clinically.

Attending Physician, Radiology
TECHNOLOGIST:

READING MD: DATE/TIME: +292
SIGNING MD: DATE/TIME: +292

THIS DOCUMENT WAS SIGNED ELECTRONICALLY
A COPY OF THIS DOCUMENT IS ON-LINE IN THE CARECAST ARCHIVE SYSTEM.
BY ELECTRONICALLY SIGNING THIS REPORT, I THE SIGNING PHYSICIAN ATTEST
THAT I HAVE PERSONALLY REVIEWED THE
FILMS FOR THE ABOVE EXAMINATION(S) AND AGREE WITH THE FINDING(S) AS
DOCUMENTED ABOVE.

Imaging

CT CHEST ABDOMEN PELVIS W CONTRAST (Order Imaging Information

+292

Imaging Information

Exam Information

Performed Procedure	Study Status	Begin Time	End Time
CT CHEST ABDOMEN PELVIS W CONTRAST	Final		N/A

Staff Information

Technologist	Transcriptionist	Assigned Physician(s)	Assigned Pool(s)
N/A	N/A	N/A	N/A

Verification Information

Signed By	Signed On
	+390

Read By

Read	Date

+390

[page 48 of 50]
+390

Signed By

Signed	Date/Time	Phone	Pager

Radiology Faculty Web Page

+390

Radiology Faculty Web Page

External Result Report

External Result Report

Reason For Exam

MALIGN NEOPL OVARY

Other Encounter Related Information

Encounter Charges

CT CHEST ABDOMEN PELVIS W CONTRAST (Order

Date: +292

Imaging

Order:

Procedure ID:

Link to CPT Codes

CPT Codes

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
	None		None

Order Details +292

Frequency	Duration	Priority	Order Class
None	None	Early	Normal

Order Providers

Authorizing Provider

Reprint Imaging Requisition

CT CHEST ABDOMEN PELVIS W CONTRAST

+292

Reason For Exam

MALIGN NEOPL OVARY

Collection Information

Collected:

Patient Information

+292

[page 49 of 50]
Additional Information

Associated Reports

View Encounter

Priority and Order Details

Collection Information.

[page 50 of 50]
Component value

Pathology Report

(NOTE)

SURGICAL PATHOLOGY REPORT

* Amended *

Case No:

Date Collected:

Date Received:

Referred by:

Copy To:

Tissue:

- 1: RIGHT TUBE + OVARY
- 2: RIGHT EXT ILIAC NODES
- 3: SIGMOID NODULE
- 4: UTERUS CERVIX LEFT TUBE + OVARY SO
- 5: SPLEEN + OMENTUM

Clinical Diagnosis:

Pelvic mass, splenic lesion.

ICD-9 code is not provided.

Gross Description:

The specimen is received in five parts.

Part one is received fresh, labeled with the patient's name [REDACTED] and medical record number [REDACTED], and designated "right tube and ovary". The specimen consists of a 300 gm salpingo-oophorectomy. The specimen measures 12.0 x 7.0 x 7.5 cm overall and is bi-lobed in appearance. There is a 7.0 x 2.5 x 0.7 cm portion of peripherally-associated fat received with the specimen. Sectioning reveals a solid component of the ovary measuring 7.0 x 6.0 x 6.5 cm overall. There is no visible surface excrescence. Grossly, there is an area of hair that is consistent with a dermoid cyst. There is an attached segment of fallopian tube measuring 7.3 cm in length with an average diameter of 1.0 cm. A representative portion of the solid component of the ovarian mass is submitted for frozen section diagnosis. The diagnosis reads, "FS1A: Ovary, right, oophorectomy: Poorly differentiated serous adenocarcinoma (in cystic teratoma on gross exam).", and called to the OR at [REDACTED] by [REDACTED]. The frozen section control is submitted in cassette 1A. Additional representative sections are submitted as follows:

- 1B: Representatives of fallopian tube
- 1C: Representative of dermoid cyst
- 1D: Additional representatives of solid portion of ovary

Part two is received fresh, labeled with the patient's name [REDACTED] and

ICD-0-3

Carcinoma, serous (8441/3) and
clear cell (8310/3)
Code to highest = 8441/3

Site: ovary, NOS C56.9

ICD-10

C56.9

hw
7/10/15

Source: NCI Genomic Data Commons file 67b743e6-f9b2-4adc-98cc-9870a65c6b8e (ER0009 ER-ABO1 Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).